Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A1AI, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A1AI-01A (Primary Tumor).

1CD-0-3
Carcinoma, medullary, NOS 8510/3
Path Site Code: breast, upper outer quadrant C50.4
12/21/10 lw
CQCF Site: breast, NOS C50.9

Final diagnosis

Breast, left, simple mastectomy: Medullary carcinoma forming a 4.5 x 2.0 x 2.0 cm well circumscribed mass (AJCC p T2) in the upper outer quadrant associated with prior biopsy site. The surgical margins are widely negative. Seen with Dr.

Lymph nodes, left axillary sentinel, excision: Multiple (5) left axillary sentinel lymph nodes are negative for tumor. Blue dye is not identified in any of the five left axillary sentinel lymph nodes. (AJCC pN0(i-)). Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression.

Source: NCI Genomic Data Commons file 91d471da-486a-4a9f-9624-aad0e2847f18 (TCGA-AR-A1AI.F5CAE962-5347-46FA-86EE-169121BED547.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).